Somatic mutation profile of tumor specimen C3N-03042-04 (aliquot CPT0235460006) from CPTAC case C3N-03042, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 67.3 years (24,572 days).
Specimen C3N-03042-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e40cc44-4534-4316-955c-1a4730918c84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03042-71 (Blood Derived Normal), aliquot CPT0235610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d5b145-d884-4c1d-935b-86028f477e05

The open-access MAF lists 125 somatic variants for this specimen: 77 protein-altering or splice-affecting, 30 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 30, Nonsense Mutation 7, Intron 6, 3'UTR 6, 3'Flank 3, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 2, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs56315533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPH | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs569811757, COSV57971139; called by muse, mutect2, varscan2
- CCDC87 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs762394264, COSV59579483, COSV59579788; called by muse, mutect2, varscan2
- DCAF4L2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 111/796 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.49); catalogued as COSV99081984; called by muse, mutect2, varscan2
- DPYD | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746115989; called by muse, mutect2, varscan2
- DYM | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53992756; called by muse, mutect2, varscan2
- EEF1B2 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV51908723; called by muse, mutect2, varscan2
- FMO3 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV63007319; called by muse, mutect2, varscan2
- G6PC | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 91/466 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs374766396, COSV99520832; called by muse, mutect2, varscan2
- GRXCR1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368508448, COSV101295710; called by muse, mutect2, varscan2
- IRF6 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022378, CM1010272, COSV65418637, COSV65419488; called by muse, mutect2, varscan2
- KAZALD1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64630263; called by muse, mutect2, varscan2
- KIF4A | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV65545311; called by muse, mutect2, varscan2
- LIMCH1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs531782327; called by muse, mutect2, varscan2
- LRP6 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 141/527 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV53785725; called by muse, mutect2, varscan2
- MORN1 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs377347349; called by muse, mutect2, varscan2
- MYO16 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 45/203 reads (22%) | catalogued as COSV51780320; called by muse, mutect2, varscan2
- NECTIN4 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.153); catalogued as rs200474573, COSV100919823; called by muse, mutect2, varscan2
- PHLPP2 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV62423884; called by muse, mutect2, varscan2
- PI4K2A | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs763253633; called by muse, mutect2, varscan2
- PKD1L1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV56964690; called by muse, mutect2, varscan2
- PLXNA1 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 103/486 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs749976520; called by muse, mutect2, varscan2
- RAD21L1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV55733094; called by muse, mutect2, varscan2
- SLC7A1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.155); catalogued as rs766898178; called by muse, mutect2, varscan2
- SULT2B1 | c.757A>G p.T253A (on ENST00000201586 / NM_177973.2; = p.T238A on NM_004605.2) | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1430367051; called by muse, mutect2, varscan2
- SV2A | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV104427241, COSV64966407; called by muse, mutect2, varscan2
- SYDE1 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618058; called by muse, mutect2, varscan2
- TADA3 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 38/135 reads (28%) | catalogued as rs1274734338, COSV55028266; called by muse, mutect2, varscan2
- TBC1D1 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54719868; called by muse, mutect2, varscan2
- TEP1 | c.5199_5202del p.F1733Lfs*34 | Frame Shift Del (DEL) | VAF 24/146 reads (16%) | catalogued as rs759562202; called by pindel, varscan2
- TM9SF3 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762042642; called by muse, mutect2, varscan2
- UBE3D | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772009043; called by muse, mutect2, varscan2
- ABCG8 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 152/639 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADGRV1 | c.3025C>A p.P1009T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG13 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); called by mutect2, varscan2
- APOB | c.1619A>T p.D540V | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AR | c.1979T>G p.L660R | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAG2 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAPN8 | c.119T>C p.L40S | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCND1 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 64/999 reads (6%) | called by muse, mutect2
- CHEK2 | c.1676C>T p.S559F (on ENST00000382580 / NM_001005735.2; = p.S516F on NM_007194.4) | Missense Mutation (SNP) | VAF 98/514 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- COL28A1 | c.3065C>T p.S1022L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF8L2 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DDAH1 | c.525G>C p.K175N | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRT2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ECPAS | c.2760A>T p.E920D | Missense Mutation (SNP) | VAF 126/269 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EYS | c.3424G>T p.G1142* | Nonsense Mutation (SNP) | VAF 76/240 reads (32%) | called by muse, mutect2, varscan2
- FBXL22 | c.354-8C>A | Splice Region (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- GFRA4 | c.476C>T p.S159L (on ENST00000319242 / NM_145762.3; = p.R133C on NM_022139.4) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNMT | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV1-40 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 151/320 reads (47%) | called by muse, mutect2, varscan2
- KASH5 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIN54 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- LRBA | c.4133del p.L1378Cfs*23 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | called by mutect2, pindel, varscan2
- MAP1A | c.5861G>C p.R1954T | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NCAPD3 | c.3428C>T p.S1143L | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OR2F2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PHACTR3 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 81/319 reads (25%) | called by muse, mutect2, varscan2
- PTPRK | c.3748_3749insAT p.P1250Hfs*7 (on ENST00000368215 / NM_001291984.2; = p.P1251Hfs*7 on NM_002844.4) | Frame Shift Ins (INS) | VAF 25/196 reads (13%) | called by pindel, varscan2
- SHANK1 | c.5227C>G p.P1743A | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCAD1 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 96/375 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SRP72 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SYNE2 | c.10243G>C p.E3415Q | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- SYT3 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TCF12 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 98/506 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- THNSL2 | c.224-1G>T p.X75_splice | Splice Site (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- TNR | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53 | c.485_488dup p.K164Lfs*18 | Frame Shift Ins (INS) | VAF 62/254 reads (24%) | called by mutect2, pindel, varscan2
- TRAIP | c.98+1G>A p.X33_splice | Splice Site (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- TRIM10 | c.931C>G p.H311D | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIO | c.6105G>T p.E2035D | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRIP11 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 41/184 reads (22%) | called by muse, mutect2, varscan2
- TRPV2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TUBAL3 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TWIST1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 123/460 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZSCAN26 | c.667G>A p.A223T (on ENST00000623276 / NM_001111039.2; = p.A89T on NM_152736.5) | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZWINT | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ADGRA1 | c.630G>A p.E210= | Silent (SNP) | VAF 47/210 reads (22%) | called by muse, mutect2, varscan2
- AHDC1 | c.1443C>T p.I481= | Silent (SNP) | VAF 103/453 reads (23%) | called by muse, mutect2, varscan2
- AP3D1 | c.3084C>T p.D1028= | Silent (SNP) | VAF 58/271 reads (21%) | catalogued as rs374725507; called by muse, mutect2, varscan2
- ARRDC2 | c.918C>T p.P306= | Silent (SNP) | VAF 45/296 reads (15%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2817C>T p.F939= | Silent (SNP) | VAF 71/308 reads (23%) | catalogued as rs146988005, COSV100327928; called by muse, mutect2, varscan2
- BTBD9 | c.708G>T p.L236= | Silent (SNP) | VAF 68/396 reads (17%) | called by muse, mutect2, varscan2
- CLYBL | c.57G>A p.L19= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as rs1242910871; called by muse, mutect2, varscan2
- FES | c.1191G>A p.P397= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs1202429225; called by muse, mutect2, varscan2
- IGHV4-28 | c.306G>C p.L102= | Silent (SNP) | VAF 135/574 reads (24%) | called by muse, mutect2
- IGLV1-36 | c.18C>T p.L6= | Silent (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2
- IL17RD | c.1734C>G p.V578= | Silent (SNP) | VAF 68/267 reads (25%) | called by muse, mutect2, varscan2
- KIF7 | c.4017G>T p.R1339= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.2508G>C p.L836= | Silent (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- MDGA1 | c.738G>A p.V246= | Silent (SNP) | VAF 91/494 reads (18%) | called by muse, mutect2, varscan2
- METTL15 | c.55T>C p.L19= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
- METTL26 | c.21G>A p.A7= | Silent (SNP) | VAF 67/279 reads (24%) | called by muse, mutect2, varscan2
- NCAPD2 | c.639C>T p.H213= | Silent (SNP) | VAF 95/386 reads (25%) | called by muse, mutect2, varscan2
- NELL1 | c.376C>A p.R126= | Silent (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- NPY5R | c.417G>A p.R139= | Silent (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- PPT2 | c.741C>T p.T247= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as rs760381432; called by muse, mutect2, varscan2
- PTGR2 | c.750C>T p.I250= | Silent (SNP) | VAF 64/247 reads (26%) | called by muse, mutect2, varscan2
- RALY | c.615G>A p.L205= (on ENST00000246194 / NM_016732.3; = p.L189= on NM_007367.4) | Silent (SNP) | VAF 47/215 reads (22%) | called by muse, mutect2, varscan2
- RGP1 | c.873A>G p.E291= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs951244483; called by muse, mutect2, varscan2
- SHISA5 | c.408C>T p.Y136= | Silent (SNP) | VAF 63/246 reads (26%) | called by muse, mutect2, varscan2
- SOX3 | c.1173C>T p.R391= | Silent (SNP) | VAF 12/269 reads (4%) | called by muse, mutect2
- SZT2 | c.3294C>T p.S1098= (on ENST00000634258 / NM_001365999.1; = p.S1041= on NM_015284.4) | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as rs775399382; called by muse, mutect2, varscan2
- TMEM63A | c.1956C>T p.F652= | Silent (SNP) | VAF 76/308 reads (25%) | catalogued as rs759816538; called by muse, mutect2, varscan2
- TTLL8 | c.417C>A p.I139= | Silent (SNP) | VAF 81/300 reads (27%) | catalogued as COSV56729684; called by muse, mutect2, varscan2
- ZFHX4 | c.9174G>T p.L3058= | Silent (SNP) | VAF 56/235 reads (24%) | catalogued as rs1244064781; called by muse, mutect2, varscan2
- ZPBP2 | c.78C>T p.F26= | Silent (SNP) | VAF 45/249 reads (18%) | called by muse, mutect2, varscan2
- AKAP7 | c.-82C>G | 5'UTR (SNP) | VAF 10/43 reads (23%) | catalogued as rs1049768796; called by muse, mutect2, varscan2
- CACNB3 | c.*794C>G | 3'UTR (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- CD8A | c.*231T>A | 3'UTR (SNP) | VAF 108/468 reads (23%) | called by muse, mutect2, varscan2
- CFH | c.*5A>T | 3'UTR (SNP) | VAF 70/336 reads (21%) | called by muse, mutect2, varscan2
- EPB41L3 | c.*7-29G>A | Intron (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- FAM124A | c.101-6067G>A | Intron (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- FCRLB | c.575-71G>A | Intron (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- GK | c.-64C>G | 5'UTR (SNP) | VAF 77/429 reads (18%) | called by muse, mutect2, varscan2
- METRN | c.566-23C>T | Intron (SNP) | VAF 35/122 reads (29%) | catalogued as rs536995566; called by muse, mutect2, varscan2
- MIR516A1 | n.38C>T | RNA (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2, varscan2
- MSANTD1 | chr4:3261394 G>A | 3'Flank (SNP) | VAF 80/348 reads (23%) | catalogued as rs373680247; called by muse, mutect2, varscan2
- MTURN | c.163-285G>A | Intron (SNP) | VAF 55/208 reads (26%) | catalogued as rs933915786; called by muse, mutect2, varscan2
- NT5C3A | c.*2C>A | 3'UTR (SNP) | VAF 66/290 reads (23%) | called by muse, mutect2, varscan2
- PBK | chr8:27808241 C>A | 3'Flank (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- ROPN1B | c.116+58G>T | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- STIMATE | chr3:52836667 C>G | 3'Flank (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2
- UNC119 | c.*7G>A | 3'UTR (SNP) | VAF 114/532 reads (21%) | catalogued as rs370209476; called by muse, mutect2, varscan2
- XIAP | c.*724A>T | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
